Somatic mutation profile of tumor specimen BA2768D (aliquot aq-BA2768D) from BEATAML1.0 case 2569, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.7 years (22,914 days).
Specimen BA2768D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c87d0ffb-c2b1-4ba4-89d8-b37b407a3eb0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2178D (Solid Tissue Normal), aliquot aq-BA2178D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbcc4b4b-23ec-4c76-abf5-a81dc504874e

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, 3'Flank 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC22A10 | c.904G>T p.V302F | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs772344532; called by muse, mutect2
- FNDC3A | c.293C>G p.P98R (on ENST00000492622 / NM_001079673.2; = p.P42R on NM_014923.5) | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- HELZ | c.2923G>T p.V975F | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2
- REXO2 | c.528C>A p.C176* | Nonsense Mutation (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- DMKN | c.1164C>T p.A388= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as rs1039415093; called by muse, mutect2
- FREM1 | c.1539C>T p.N513= | Silent (SNP) | VAF 17/249 reads (7%) | catalogued as rs747595418; called by muse, mutect2
- CICP28 | chr7:56812113 A>G | 3'Flank (SNP) | VAF 4/41 reads (10%) | catalogued as rs371246121; called by muse, mutect2
- FOXP3 | c.1147-12G>T | Intron (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100873167; called by muse, mutect2
